Somatic mutation profile of tumor specimen MMRF_1614_1_BM_CD138pos (aliquot MMRF_1614_1_BM_CD138pos_T2_KHS5U_K14085) from MMRF case MMRF_1614, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,144 days).
Specimen MMRF_1614_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cd98238-75f6-4ec3-b441-b6c19d053a27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1614_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1614_1_PB_Whole_C2_KHS5U_K14075; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8439509d-55cc-42f6-be72-066ecff6609e

The open-access MAF lists 186 somatic variants for this specimen: 86 protein-altering or splice-affecting, 25 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, 3'UTR 43, Silent 25, Intron 17, 3'Flank 6, 5'UTR 5, Nonsense Mutation 4, RNA 3, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 16/125 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1345545620, COSV65887938; called by muse, mutect2, varscan2
- ARFGEF3 | c.6118G>A p.A2040T | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs760910446, COSV52453970; called by muse, mutect2, varscan2
- CALCOCO1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759818625; called by muse, mutect2, varscan2
- CKAP5 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs750746539; called by muse, mutect2, varscan2
- COL6A1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs373731596; called by muse, mutect2, varscan2
- DNAH10 | c.12925C>T p.R4309W (on ENST00000409039; = p.R4248W on NM_207437.3) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs370371005; called by muse, mutect2, varscan2
- DPPA4 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs990657669; called by muse, mutect2, varscan2
- EMILIN2 | c.2240C>T p.T747M | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201404612; called by muse, mutect2, varscan2
- FBN1 | c.5815G>A p.G1939R | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57323652; called by muse, mutect2, varscan2
- HMCN1 | c.12612dup p.D4205Rfs*7 | Frame Shift Ins (INS) | VAF 55/253 reads (22%) | catalogued as rs765345975; called by mutect2, pindel, varscan2
- IGFBP6 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); catalogued as rs755966753, COSV56857348; called by muse, mutect2, varscan2
- IGHJ6 | c.35A>C p.K12T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | PolyPhen benign (0.006); catalogued as rs140411866; called by muse, varscan2
- IGKV4-1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs186251122; called by muse, mutect2, varscan2
- IGLL5 | c.177C>G p.S59R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs569308745, COSV104440313, COSV73250973; called by muse, mutect2, varscan2
- IGLV3-1 | c.135A>C p.K45N | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183724895; called by muse, varscan2
- KCNA4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 95/132 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs775798928, COSV60250783; called by muse, mutect2, varscan2
- KRTAP10-5 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs782057050; called by muse, mutect2, varscan2
- LYST | c.6305G>A p.R2102H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs201095810, COSV67703413; called by muse, mutect2
- MPDZ | c.4642C>A p.L1548I | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); catalogued as COSV59919698; called by muse, mutect2
- MYO10 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.028); catalogued as COSV57020939; called by muse, mutect2, varscan2
- NKPD1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs758503732; called by muse, mutect2, varscan2
- NLRP2 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs776254226, COSV54752647; called by muse, mutect2
- NOC2L | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1359441783; called by muse, mutect2, varscan2
- ORAI1 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as rs555170508; called by muse, mutect2, varscan2
- PTPRT | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62011954; called by muse, mutect2, varscan2
- RBMXL3 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.176); catalogued as COSV100407571; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2
- RYR1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs574357386; called by muse, mutect2, varscan2
- SS18 | c.1163G>T p.G388V (on ENST00000415083 / NM_001007559.3; = p.G357V on NM_005637.3) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs755200495; called by muse, mutect2, varscan2
- TBX22 | c.1563G>T p.*521Yext*1 | Nonstop Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV64786382; called by muse, mutect2, varscan2
- TTC30B | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as rs768799706; called by muse, mutect2
- WNT3 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759165713, COSV99842946; called by muse, mutect2, varscan2
- ZNF426 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 24/346 reads (7%) | catalogued as rs1258556157, COSV53468958; called by muse, mutect2
- ZNF587B | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs781617982; called by muse, mutect2
- ABCD4 | c.1560G>A p.W520* | Nonsense Mutation (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2, varscan2
- ABCG1 | c.707C>A p.P236Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADARB1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 97/244 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AEBP2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.9529G>A p.V3177M | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ANKRD30B | c.2812A>C p.T938P | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- BIRC2 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BTAF1 | c.4283G>A p.R1428K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C8orf34 | c.140A>C p.Q47P | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2, varscan2
- CCDC152 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- CCR3 | c.1021T>C p.S341P | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CELSR3 | c.8630C>A p.T2877N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CNOT7 | c.120C>T p.D40= | Splice Region (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- CUBN | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- DDX53 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 71/75 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DNAH10 | c.1867T>C p.Y623H (on ENST00000409039; = p.Y562H on NM_207437.3) | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAHD2A | c.882+4G>A | Splice Region (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2
- FAM110D | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- FAM214A | c.1721_1725del p.E574Vfs*16 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- FAM71E1 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, mutect2
- FHOD1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- FIGNL2 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GPC2 | c.1121C>A p.T374N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, varscan2
- IGHV2-70D | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- INAFM1 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNV1 | c.301T>A p.Y101N | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MRPL37 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- MTMR12 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- MXRA5 | c.3060T>G p.D1020E | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEBL | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NR1H4 | c.1369T>C p.F457L (on ENST00000551379 / NM_001206993.2; = p.F443L on NM_005123.4) | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NRXN2 | c.4678C>A p.L1560M | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2
- OR4C15 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- PACS2 | c.758_760delinsT p.Q253Lfs*38 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | called by pindel, varscan2*
- PALLD | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLDB1 | c.1459G>T p.A487S | Missense Mutation (SNP) | VAF 129/412 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP6C | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RUNX1T1 | c.403C>T p.Q135* (on ENST00000265814 / NM_001198628.1; = p.Q108* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- RYR1 | c.12473G>A p.R4158H | Missense Mutation (SNP) | VAF 48/441 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RYR2 | c.9593C>T p.P3198L | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SLC17A7 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SORCS3 | c.2819G>A p.S940N | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- SS18 | c.1162G>T p.G388* (on ENST00000415083 / NM_001007559.3; = p.G357* on NM_005637.3) | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- TACC2 | c.1559A>G p.K520R | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2
- TRGV10 | c.155G>T p.W52L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- USP27X | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- VWDE | c.2985del p.T996Lfs*22 | Frame Shift Del (DEL) | VAF 28/308 reads (9%) | called by mutect2, pindel
- ZNF304 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF462 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF541 | c.2519G>A p.C840Y | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP6V0A4 | c.522C>T p.A174= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as rs563386735, COSV100023260, COSV59477334; called by muse, mutect2, varscan2
- BAHCC1 | c.6588C>T p.Y2196= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs782228431, COSV100311432; called by muse, mutect2, varscan2
- C14orf119 | c.264A>G p.P88= | Silent (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- CACNG8 | c.873C>T p.P291= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs577312704; called by muse, mutect2, varscan2
- CFAP57 | c.2577C>T p.T859= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- DOCK9 | c.1335C>T p.V445= (on ENST00000376460 / NM_001366676.2; = p.V446= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV59627116; called by muse, mutect2, varscan2
- DOP1B | c.354G>A p.A118= | Silent (SNP) | VAF 27/300 reads (9%) | catalogued as rs151160436; called by muse, mutect2
- EN1 | c.165G>A p.A55= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- GRIK2 | c.1305T>G p.V435= | Silent (SNP) | VAF 97/205 reads (47%) | called by muse, mutect2, varscan2
- HDHD2 | c.282T>A p.V94= | Silent (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.2055G>A p.K685= | Silent (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- NAV3 | c.3156C>T p.P1052= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV57105275, COSV99894731; called by muse, mutect2, varscan2
- OR4X1 | c.654C>T p.I218= | Silent (SNP) | VAF 66/201 reads (33%) | called by muse, mutect2, varscan2
- PACC1 | c.567G>A p.L189= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV54790025; called by muse, mutect2, varscan2
- PCDHA5 | c.387G>A p.P129= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV65350156, COSV65352674; called by muse, mutect2, varscan2
- PLEKHF1 | c.69G>A p.G23= | Silent (SNP) | VAF 23/320 reads (7%) | catalogued as COSV71410232; called by muse, mutect2
- RUFY4 | c.369G>A p.L123= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- SH2D7 | c.654C>T p.I218= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- SLC26A3 | c.1368T>G p.A456= | Silent (SNP) | VAF 19/541 reads (4%) | called by muse, mutect2
- STK40 | c.537C>T p.Y179= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs375891919; called by muse, mutect2, varscan2
- TRIM26 | c.982C>T p.L328= | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- TRMT1 | c.48G>C p.R16= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs200989466; called by muse, mutect2, varscan2
- VSIG8 | c.225C>T p.N75= | Silent (SNP) | VAF 80/157 reads (51%) | catalogued as rs778942952, COSV63652976; called by muse, mutect2, varscan2
- WNK2 | c.645G>A p.T215= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs777728277; called by muse, mutect2, varscan2
- ZXDC | c.714C>T p.F238= | Silent (SNP) | VAF 25/227 reads (11%) | catalogued as COSV60448320; called by muse, mutect2, varscan2
- AC083864.1 | n.1368A>G | RNA (SNP) | VAF 36/371 reads (10%) | called by muse, mutect2, varscan2
- AC120036.1 | n.104+5609G>T | Intron (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.*534G>T | 3'UTR (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- ADAMTS5 | c.*2102T>C | 3'UTR (SNP) | VAF 70/149 reads (47%) | called by muse, mutect2, varscan2
- ADI1 | c.-25G>A | 5'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- AK5 | c.699+15914G>C | Intron (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4436G>A | Intron (SNP) | VAF 17/31 reads (55%) | catalogued as rs769377288; called by muse, mutect2, varscan2
- ATF6 | c.*2744T>C | 3'UTR (SNP) | VAF 46/82 reads (56%) | called by muse, mutect2
- BRI3BP | c.*4184T>G | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- CDADC1 | c.-76G>C | 5'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- CDK6 | c.*2186A>C | 3'UTR (SNP) | VAF 101/146 reads (69%) | called by muse, mutect2, varscan2
- CRNKL1 | c.*1322G>T | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- CTSS | c.*2796C>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- CYCS | c.*2033G>C | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- DCLK1 | c.*49A>G | 3'UTR (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- DDX39B | c.-3+655G>T | Intron (SNP) | VAF 80/161 reads (50%) | called by muse, mutect2, varscan2
- DOCK4 | c.*1857A>C | 3'UTR (SNP) | VAF 60/89 reads (67%) | called by muse, mutect2, varscan2
- DSC2 | c.-193G>T | 5'UTR (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- EDNRA | c.*2237A>T | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- ERG | chr21:38380762 G>T | 3'Flank (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2
- FAM71D | c.1190-390_1190-386del | Intron (DEL) | VAF 40/179 reads (22%) | catalogued as rs1488489371; called by mutect2, pindel, varscan2
- FGD4 | c.*2430T>G | 3'UTR (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- GRK7 | c.*803C>T | 3'UTR (SNP) | VAF 58/97 reads (60%) | called by muse, mutect2, varscan2
- HBD | chr11:5232713 C>T | 3'Flank (SNP) | VAF 16/518 reads (3%) | called by muse, mutect2
- HPGD | c.421+681G>A | Intron (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- KAT6A | c.*654C>T | 3'UTR (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- KCNH5 | c.*609T>A | 3'UTR (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- KCNQ1 | c.*112del | 3'UTR (DEL) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- KNSTRN | c.823-70G>A | Intron (SNP) | VAF 14/494 reads (3%) | called by muse, mutect2
- KREMEN1 | chr22:29146085 G>T | 3'Flank (SNP) | VAF 74/248 reads (30%) | called by muse, mutect2, varscan2
- KRT75 | c.1162-12C>A | Intron (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- MRGPRG | chr11:3222099 C>A | 5'Flank (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- NIN | chr14:50723337 G>A | 3'Flank (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-32T>G | Intron (SNP) | VAF 28/42 reads (67%) | called by muse, mutect2
- NPS | c.*102A>G | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- NTRK3 | c.*16785A>C | 3'UTR (SNP) | VAF 85/121 reads (70%) | called by muse, mutect2, varscan2
- PABPC1 | c.644-90T>G | Intron (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- PARS2 | c.*160C>T | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- PDGFD | c.*1430T>C | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.*1264C>G | 3'UTR (SNP) | VAF 62/278 reads (22%) | called by muse, mutect2, varscan2
- PIGW | c.*566T>C | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- PRKAR1B | c.*642G>A | 3'UTR (SNP) | VAF 11/296 reads (4%) | catalogued as rs903900765; called by muse, mutect2
- PSMG3 | chr7:1567574 T>C | 3'Flank (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- RTF1 | c.*2516A>G | 3'UTR (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- RTKN2 | c.*2034G>A | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- SAMD5 | c.*2988C>A | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- SECISBP2L | c.*1642A>G | 3'UTR (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- SEMA3C | c.*1966T>C | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- SEPTIN11 | c.28-621dup | Intron (INS) | VAF 56/157 reads (36%) | called by mutect2, pindel, varscan2
- SLC2A3 | c.*1921C>T | 3'UTR (SNP) | VAF 3/8 reads (38%) | catalogued as rs1344156424; called by muse, mutect2
- SLC35F4 | c.*136A>C | 3'UTR (SNP) | VAF 20/41 reads (49%) | catalogued as rs926765581; called by muse, mutect2, varscan2
- SLITRK2 | c.-3954G>A | 5'UTR (SNP) | VAF 62/62 reads (100%) | called by muse, mutect2, varscan2
- SMAD9 | c.*3495T>C | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- SMAP1 | c.118+481C>T | Intron (SNP) | VAF 13/71 reads (18%) | catalogued as rs1201958971; called by muse, mutect2
- SMAP1 | c.118+483C>T | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2
- SMPD4BP | n.2607T>G | RNA (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- SPART | c.*580T>G | 3'UTR (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- SRGAP3 | c.801+14G>A | Intron (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- STEAP4 | c.*5742T>C | 3'UTR (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- STK32A | c.*66A>C | 3'UTR (SNP) | VAF 171/527 reads (32%) | called by muse, mutect2, varscan2
- SYBU | c.*471C>G | 3'UTR (SNP) | VAF 55/120 reads (46%) | called by muse, mutect2, varscan2
- TNFRSF6B | c.*52A>C | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.207-195G>A | Intron (SNP) | VAF 15/50 reads (30%) | catalogued as rs909478515; called by muse, mutect2, varscan2
- TSPYL5 | c.*638C>G | 3'UTR (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- UGT2B10 | c.*39G>T | 3'UTR (SNP) | VAF 163/356 reads (46%) | called by muse, mutect2, varscan2
- UNC13B | c.*895C>T | 3'UTR (SNP) | VAF 102/305 reads (33%) | called by muse, mutect2, varscan2
- VGLL3 | c.*1367T>G | 3'UTR (SNP) | VAF 29/52 reads (56%) | catalogued as rs1049574291; called by muse, mutect2, varscan2
- VPS26C | chr21:37220340 G>A | 3'Flank (SNP) | VAF 18/490 reads (4%) | catalogued as rs1002143314; called by muse, mutect2
- VPS41 | c.*1316A>C | 3'UTR (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- ZFP82 | c.-65G>A | 5'UTR (SNP) | VAF 106/735 reads (14%) | called by muse, mutect2, varscan2
- ZNF300P1 | n.1550G>A | RNA (SNP) | VAF 157/259 reads (61%) | catalogued as rs1254298419; called by muse, mutect2, varscan2
- ZNF419 | c.34-31G>A | Intron (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2
- ZNF525 | c.*2751G>A | 3'UTR (SNP) | VAF 12/161 reads (7%) | called by muse, mutect2
- ZNF561 | c.115-81T>C | Intron (SNP) | VAF 40/480 reads (8%) | called by muse, mutect2
- ZNF782 | c.*983A>G | 3'UTR (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
